Somatic mutation profile of tumor specimen TCGA-VB-A8QN-01A (aliquot TCGA-VB-A8QN-01A-11D-A382-10) from TCGA case TCGA-VB-A8QN, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 55.5 years (20,270 days).
Specimen TCGA-VB-A8QN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5491b8af-c270-4062-a839-fe1a7518c6b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VB-A8QN-10A (Blood Derived Normal), aliquot TCGA-VB-A8QN-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95f9ce2b-12d5-444c-98d2-f04603c45450

The open-access MAF lists 185 somatic variants for this specimen: 126 protein-altering or splice-affecting, 56 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 56, Nonsense Mutation 16, Splice Site 4, In Frame Del 3, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GHR | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as rs121909358, CM910179, COSV100049546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 39/163 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 26/152 reads (17%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1842C>G p.S614R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV52882793, COSV52882958; called by muse, mutect2, varscan2
- ABCD4 | c.653T>A p.L218Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.574); catalogued as COSV100084409; called by muse, mutect2, varscan2
- ACAD10 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs147958599; called by muse, mutect2, varscan2
- ADAM21 | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99961252; called by muse, mutect2, varscan2
- ADARB2 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs138785387; called by muse, mutect2, varscan2
- ADGRL2 | c.1047C>A p.N349K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99590395; called by muse, mutect2, varscan2
- AMOT | c.1679C>A p.T560N (on ENST00000371959 / NM_001113490.1; = p.T151N on NM_133265.3) | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as COSV100495351; called by muse, mutect2, varscan2
- APBA2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs149847107; called by muse, mutect2, varscan2
- ARID5B | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99690114; called by muse, mutect2, varscan2
- AURKB | c.787T>A p.C263S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV100298816; called by muse, mutect2, varscan2
- BPIFA1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs758644147, COSV62823987; called by muse, mutect2, varscan2
- CABIN1 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as rs556308783, COSV99573679; called by muse, mutect2, varscan2
- CACNA1G | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs573756072, COSV61729725; called by muse, varscan2
- CATSPERE | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.529); catalogued as COSV100835273; called by muse, mutect2, varscan2
- CBLN2 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as rs1193984103, COSV54053560; called by muse, mutect2, varscan2
- CCDC181 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100890358; called by muse, mutect2, varscan2
- CFH | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 89/529 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100808893; called by muse, mutect2, varscan2
- CRTAM | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs748217702, COSV57072095; called by muse, mutect2, varscan2
- CTDSP2 | c.672A>G p.I224M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV101143049, COSV66079727; called by muse, mutect2, varscan2
- DCHS1 | c.3406C>G p.P1136A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV100202333; called by muse, mutect2
- DISC1 | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1483308206, COSV99698274; called by muse, mutect2, varscan2
- DNMT3L | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99533374; called by muse, mutect2, varscan2
- DSG1 | c.2041A>G p.M681V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as rs1310285037, COSV99936278; called by muse, mutect2, varscan2
- DSG4 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs753512705, COSV100356167; called by muse, mutect2, varscan2
- EGR4 | c.1378C>T p.R460* (on ENST00000545030; = p.R357* on NM_001965.4) | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV101474258; called by muse, mutect2
- EIPR1 | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV101182219; called by muse, mutect2, varscan2
- EPHA3 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100347003, COSV60698954, COSV60717592; called by muse, mutect2, varscan2
- EPHA6 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs778168979, COSV67558533; called by muse, mutect2, varscan2
- FAM47B | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs1569204073, COSV100264488; called by muse, mutect2, varscan2
- FMN2 | c.5098G>T p.G1700* | Nonsense Mutation (SNP) | VAF 32/165 reads (19%) | catalogued as COSV100146437; called by muse, mutect2, varscan2
- FMO2 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs187393653, COSV52950089, COSV99269261; called by muse, mutect2, varscan2
- FOXO1 | c.486C>G p.N162K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279288612, COSV101092080; called by muse, mutect2, varscan2
- FSCB | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV100469578, COSV61219592; called by muse, mutect2, varscan2
- GABRA1 | c.776T>A p.L259Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99196123; called by muse, mutect2, varscan2
- GABRR3 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357273438, COSV101512325; called by muse, mutect2, varscan2
- H1-4 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs199659170, COSV56799624, COSV56804339; called by muse, mutect2, varscan2
- H1-4 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.665); catalogued as rs201935674, COSV56799837, COSV56800144, COSV99175288; called by muse, mutect2, varscan2
- H1-5 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.14); catalogued as rs199758872, COSV100137995; called by muse, mutect2, varscan2
- HEATR5A | c.2639G>A p.W880* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV101120293; called by muse, mutect2, varscan2
- HLA-B | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as rs151341159, CM1412116, COSV69520706; called by muse, mutect2
- IGHG2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1439659583; called by muse, varscan2
- KALRN | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375081975; called by muse, mutect2, varscan2
- KANK4 | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); catalogued as rs746099288, COSV100443270; called by muse, mutect2, varscan2
- KAT6A | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99705575; called by muse, mutect2, varscan2
- KCNJ3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.054); catalogued as rs868672401, COSV54530586, COSV54543402; called by muse, mutect2, varscan2
- KDR | c.3064C>T p.R1022* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55759731; called by muse, mutect2, varscan2
- KHDRBS2 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.164); catalogued as COSV55441329, COSV55467990, COSV55491198; called by muse, mutect2, varscan2
- LNX1 | c.1163G>T p.S388I (on ENST00000263925 / NM_001126328.3; = p.S292I on NM_032622.2) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs989152693, COSV99820268; called by muse, mutect2, varscan2
- LRAT | c.475A>C p.N159H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as COSV100312140; called by muse, mutect2, varscan2
- MACF1 | c.18818A>G p.H6273R (on ENST00000372915; = p.H4318R on NM_012090.5) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV99245764; called by muse, mutect2, varscan2
- MAGEL2 | c.2732C>A p.P911Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100046087; called by muse, mutect2, varscan2
- MAP1A | c.608T>A p.L203H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288971; called by muse, mutect2, varscan2
- MDN1 | c.2806G>A p.G936R | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV101021593, COSV65517501; called by muse, mutect2, varscan2
- MRC2 | c.2705G>A p.W902* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100316493; called by muse, mutect2, varscan2
- MSLN | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.919); catalogued as COSV53501928; called by muse, varscan2
- MTA2 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV53872234; called by muse, mutect2, varscan2
- MUC16 | c.35838A>G p.I11946M | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1352811772, COSV101200541; called by muse, mutect2, varscan2
- MUC16 | c.25097A>T p.Q8366L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV101200543; called by muse, mutect2, varscan2
- MYH1 | c.4427A>C p.K1476T | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV99876479; called by muse, mutect2, varscan2
- MYH2 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55448959; called by muse, mutect2, varscan2
- OCA2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs768169106, COSV62338519; called by muse, mutect2, varscan2
- OR4N2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100269803; called by muse, mutect2, varscan2
- OR5AP2 | c.913A>C p.K305Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100266340; called by muse, mutect2, varscan2
- OTUD4 | c.2534A>G p.N845S (on ENST00000447906 / NM_001366057.1; = p.N780S on NM_001102653.1) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as rs1471067772, COSV101486029; called by muse, mutect2, varscan2
- P2RX4 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as rs761067441, COSV100465177; called by muse, mutect2, varscan2
- P2RY6 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs139336490, COSV100573939; called by muse, mutect2, varscan2
- PAQR9 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV61417657, COSV61418619; called by muse, mutect2, varscan2
- PCDHA9 | c.1581G>C p.E527D | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.151); catalogued as COSV100969862; called by muse, mutect2
- PCDHGA7 | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs781186343, COSV53973978, COSV53991965; called by muse, mutect2, varscan2
- PCLO | c.3910C>G p.Q1304E | Missense Mutation (SNP) | VAF 114/513 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV100434885, COSV61659338; called by muse, varscan2
- PDE3A | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.323); catalogued as COSV62981270; called by muse, mutect2, varscan2
- PGR | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as rs868064003, COSV99678785; called by muse, mutect2, varscan2
- PIWIL1 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99806699; called by muse, mutect2, varscan2
- PPP1R3A | c.3265G>A p.V1089I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776274085, COSV99493559; called by muse, mutect2, varscan2
- PRAMEF14 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1446907515; called by muse, mutect2, varscan2
- PTCHD4 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143420847; called by muse, mutect2, varscan2
- PTPN6 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV100017191; called by muse, mutect2, varscan2
- PTPN6 | c.1256A>G p.D419G | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59686770; called by muse, mutect2, varscan2
- QSER1 | c.3947A>T p.K1316M (on ENST00000399302; = p.K1445M on NM_001076786.3) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV101234929; called by muse, mutect2, varscan2
- RCC2 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64905516; called by muse, mutect2, varscan2
- RGS12 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs777223492, COSV58749195; called by muse, mutect2, varscan2
- RNF40 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761600982, COSV100222232; called by muse, mutect2, varscan2
- RPTN | c.699A>C p.K233N | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV60166358; called by muse, mutect2, varscan2
- SALL3 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs533436270, COSV73306302, COSV73306776; called by muse, mutect2
- SCN2A | c.4990G>A p.G1664S | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99332149; called by muse, mutect2, varscan2
- SELENOH | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99560201; called by muse, mutect2, varscan2
- SLC5A5 | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV55833249; called by muse, mutect2, varscan2
- SLC9C2 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.129); catalogued as COSV100876899; called by muse, mutect2, varscan2
- SMPDL3B | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs767118489, COSV65855188; called by muse, mutect2, varscan2
- SOCS1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs1156507872, COSV100130431; called by muse, mutect2, varscan2
- SOX11 | c.1003T>A p.S335T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100431298; called by muse, mutect2, varscan2
- SPECC1 | c.284-1G>T p.X95_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99822456; called by muse, mutect2, varscan2
- SPEN | c.4252C>T p.R1418* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV65365496; called by muse, mutect2, varscan2
- ST8SIA6 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV101112178; called by muse, mutect2, varscan2
- STRC | c.3823G>T p.E1275* | Nonsense Mutation (SNP) | VAF 50/183 reads (27%) | catalogued as COSV101348017; called by muse, mutect2, varscan2
- TAS2R16 | c.793G>C p.V265L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99972302; called by muse, mutect2, varscan2
- TBX3 | c.1370C>T p.P457L (on ENST00000257566 / NM_016569.4; = p.P437L on NM_005996.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as rs371891930; called by muse, mutect2, varscan2
- TCTN1 | c.1391G>T p.G464V (on ENST00000551590 / NM_001173975.3; = p.G450V on NM_024549.6) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657230, COSV99657327; called by muse, mutect2, varscan2
- TFDP2 | c.726_728del p.L243del (on ENST00000489671 / NM_001178139.2; = p.L183del on NM_006286.5) | In Frame Del (DEL) | VAF 34/155 reads (22%) | catalogued as rs1439023123; called by mutect2, pindel, varscan2
- TMEM102 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99548431, COSV99548432; called by muse, mutect2, varscan2
- TMEM214 | c.1152+1G>A p.X384_splice | Splice Site (SNP) | VAF 37/144 reads (26%) | catalogued as COSV99476446; called by muse, mutect2, varscan2
- TMEM62 | c.1724T>C p.V575A | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV99543773; called by muse, mutect2, varscan2
- TTC30B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV101282802; called by muse, mutect2, varscan2
- TYRP1 | c.266T>A p.V89D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV101141401; called by muse, mutect2, varscan2
- UBE2A | c.45-2A>C p.X15_splice | Splice Site (SNP) | VAF 70/156 reads (45%) | catalogued as COSV100660517; called by muse, mutect2, varscan2
- UGGT2 | c.1338G>A p.W446* | Nonsense Mutation (SNP) | VAF 48/224 reads (21%) | catalogued as COSV100948801; called by muse, mutect2, varscan2
- UGT2B7 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV100535260; called by muse, mutect2, varscan2
- ULK4 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs748043954, COSV100094052; called by muse, mutect2, varscan2
- UNC5B | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs959583786, COSV100101034, COSV58980421; called by muse, mutect2, varscan2
- WDR36 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); catalogued as COSV72411314, COSV72411466; called by muse, mutect2, varscan2
- WDTC1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100089249; called by muse, mutect2, varscan2
- WWC3 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767459415, COSV101081625; called by muse, mutect2, varscan2
- ZBTB40 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100989068; called by muse, varscan2
- ZFAT | c.2386A>G p.I796V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100914789; called by muse, mutect2, varscan2
- ZNF135 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776610394, COSV100536591; called by muse, mutect2, varscan2
- ZNF208 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.729); catalogued as COSV101237156; called by muse, mutect2, varscan2
- ZNF273 | c.1177A>C p.K393Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100139441; called by muse, mutect2, varscan2
- ZNF571 | c.1179C>A p.C393* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100143908; called by muse, mutect2, varscan2
- ZNF80 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs1389596214, COSV57361799; called by muse, mutect2, varscan2
- ZNHIT1 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV59312784; called by muse, mutect2, varscan2
- ZP4 | c.1496-1G>A p.X499_splice | Splice Site (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100850728; called by muse, mutect2, varscan2
- GGN | c.1319_1321del p.L440del | In Frame Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- GPR52 | c.940_963del p.C314_N321del | In Frame Del (DEL) | VAF 26/160 reads (16%) | called by mutect2, pindel, varscan2
- ABCA3 | c.405C>T p.F135= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs746445304, COSV57050458, COSV57060315; called by muse, mutect2, varscan2
- ADAMTS2 | c.2985C>A p.T995= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52370353, COSV99283190; called by muse, mutect2, varscan2
- ADIPOR1 | c.321C>T p.N107= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs377163409, COSV61851279; called by muse, mutect2, varscan2
- ANO3 | c.2310G>A p.A770= | Silent (SNP) | VAF 56/189 reads (30%) | catalogued as rs766181740, COSV56789173, COSV56792211, COSV56798567; called by muse, mutect2, varscan2
- BTG2 | c.298C>T p.L100= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99305867; called by muse, mutect2, varscan2
- CALR | c.1245C>T p.D415= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs148604761, COSV100330900, COSV57124074; called by muse, varscan2
- CAMP | c.120A>G p.E40= (on ENST00000296435; = p.E37= on NM_004345.5) | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs756113182, COSV99601273; called by muse, mutect2, varscan2
- CFH | c.1062C>T p.S354= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as rs1351683602, COSV100661542; called by muse, mutect2, varscan2
- COL6A3 | c.7854C>T p.I2618= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs779948294, COSV55106938; called by muse, mutect2, varscan2
- CTC1 | c.1530C>T p.T510= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs376217684; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCAF12 | c.144C>T p.Y48= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100778380, COSV100778388; called by muse, mutect2, varscan2
- DIP2B | c.3927G>A p.P1309= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs761478498, COSV99998990; called by muse, mutect2, varscan2
- EFHC1 | c.138G>C p.G46= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV64138093; called by muse, mutect2, varscan2
- EYA1 | c.27G>A p.P9= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs763352962, COSV58174321; called by muse, mutect2, varscan2
- FAM120B | c.2616G>A p.Q872= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99379711; called by muse, mutect2, varscan2
- FDPS | c.633C>T p.L211= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100756256, COSV63114335; called by muse, mutect2, varscan2
- FGD4 | c.183A>G p.T61= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV99847394; called by muse, mutect2, varscan2
- FOXB1 | c.105G>A p.P35= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1275740755, COSV101249879; called by muse, mutect2, varscan2
- GABRB3 | c.1068C>T p.S356= | Silent (SNP) | VAF 54/258 reads (21%) | catalogued as rs369761963, COSV54674544; ClinVar: likely benign; called by muse, mutect2, varscan2
- GMPR2 | c.24G>T p.V8= (on ENST00000355299 / NM_001351022.2; = p.V26= on NM_016576.5) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV51660702, COSV51662091; called by muse, mutect2, varscan2
- GPR149 | c.1416A>G p.K472= | Silent (SNP) | VAF 63/239 reads (26%) | catalogued as COSV101078592; called by muse, mutect2, varscan2
- H1-2 | c.186G>C p.L62= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs770676686, COSV100642309, COSV59192116; called by muse, mutect2, varscan2
- H1-3 | c.186G>A p.A62= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as COSV99768812; called by muse, mutect2, varscan2
- H2AC11 | c.270C>T p.N90= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV100345844; called by muse, mutect2, varscan2
- H2BC12 | c.378G>A p.K126= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs765695435, COSV100804719, COSV63616594; called by muse, mutect2, varscan2
- H2BC21 | c.144G>A p.Q48= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as COSV100480050; called by muse, mutect2, varscan2
- H3C3 | c.174C>T p.S58= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100778306; called by muse, mutect2, varscan2
- JAG1 | c.807G>A p.P269= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs753646278, COSV54761932; called by muse, mutect2, varscan2
- KIAA1549L | c.4785G>A p.P1595= (on ENST00000321505; = p.P1892= on NM_012194.3) | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs765462279, COSV100381968; called by muse, mutect2, varscan2
- LRRN3 | c.1737T>C p.N579= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1364634153, COSV100072134; called by muse, mutect2, varscan2
- MAN2C1 | c.183G>A p.Q61= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV51227991, COSV99145618; called by muse, mutect2, varscan2
- MB21D2 | c.1239C>T p.T413= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs138837641; called by muse, mutect2, varscan2
- MC3R | c.498G>T p.V166= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV99710703; called by muse, mutect2, varscan2
- MCL1 | c.660G>A p.V220= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1021033149, COSV57189997, COSV57190026; called by muse, mutect2, varscan2
- NCAM2 | c.2193G>A p.L731= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV99524192; called by muse, mutect2, varscan2
- NOL9 | c.376C>T p.L126= | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as rs1233758911, COSV100063294; called by muse, varscan2
- NUP35 | c.571C>T p.L191= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV99717898; called by muse, mutect2, varscan2
- OBSCN | c.20022C>T p.N6674= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs200703788, COSV100804849; called by muse, mutect2, varscan2
- PAX7 | c.537C>T p.D179= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100946903; called by muse, mutect2, varscan2
- PCDHA11 | c.2382C>T p.H794= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as rs1554165663, COSV100252399; called by muse, mutect2, varscan2
- PCDHA2 | c.1218G>A p.S406= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs782764086, COSV100973464, COSV100974050; called by muse, mutect2, varscan2
- PIM1 | c.21C>T p.N7= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs756412850, COSV100998728, COSV65166667; called by muse, mutect2, varscan2
- PLEC | c.6690G>A p.A2230= (on ENST00000322810 / NM_201380.4; = p.A2120= on NM_000445.5) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs539190005, COSV100516506; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RGS8 | c.6G>A p.A2= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs747431127, COSV99276797; called by muse, mutect2, varscan2
- RHOB | c.534G>A p.A178= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99695313; called by muse, mutect2, varscan2
- SEMA3E | c.780C>T p.H260= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs533306215, COSV100317382; called by muse, mutect2, varscan2
- SEPTIN4 | c.768C>T p.C256= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs144640338; called by muse, mutect2, varscan2
- SLC17A6 | c.435C>T p.I145= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs557561735, COSV99581984; called by muse, mutect2, varscan2
- SRARP | c.312C>G p.A104= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100272994; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.66G>A p.L22= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as COSV100602930; called by muse, mutect2, varscan2
- TCF3 | c.39C>T p.D13= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53649836, COSV99514336; called by muse, mutect2, varscan2
- TGM7 | c.945C>T p.I315= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs1239062396, COSV101476887; called by muse, mutect2, varscan2
- TH | c.678G>A p.S226= (on ENST00000381178 / NM_199292.3; = p.S195= on NM_000360.4) | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs376615793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPD52L2 | c.579G>A p.A193= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs143876889, COSV53862584; called by muse, mutect2, varscan2
- UAP1 | c.639G>A p.K213= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99617901; called by muse, mutect2, varscan2
- VPS13D | c.8601C>T p.N2867= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV99167682; called by muse, mutect2, varscan2
- DST | c.4297-3927G>A | Intron (SNP) | VAF 33/149 reads (22%) | catalogued as COSV99758333; called by muse, mutect2, varscan2
- HOATZ | chr11:111513005 C>A | 5'Flank (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- XBP1 | c.227+292C>T | Intron (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99321498, COSV99321722; called by muse, mutect2, varscan2
